FM case AD15950 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and ill-defined digestive organs.
https://portal.gdc.cancer.gov/cases/0b4eba67-134b-42f4-ba67-0d5b240941d6

Male, 62.6 years: Neuroendocrine carcinoma, NOS (ICD-O-3 8246/3) of the gastrointestinal tract; metastasis biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 90% (pathologist estimate recorded by GDC). Sample type: Metastatic.
